Somatic mutation profile of tumor specimen 0DSTYI from CCDI case PBCIUT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.4 years (5,990 days).
Specimen 0DSTYI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2d4f765-994f-4cec-84a4-3b91322558fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSTY9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ad465a1-ffd0-4cac-aed0-ed557f5a83a8

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERVV-2 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as rs528566052; called by muse, mutect2, varscan2
- HBP1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 30/581 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as rs1452649288, COSV56018019; called by muse, mutect2
- MAGEB6 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs201693952, COSV66872886; called by muse, mutect2
- PLCL1 | c.907T>A p.F303I | Missense Mutation (SNP) | VAF 141/733 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778339950; called by muse, mutect2, varscan2
- TFF1 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs150281749; called by muse, mutect2
- MAFG | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 10/348 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.412); called by muse, mutect2
- MERTK | c.2585C>G p.P862R | Missense Mutation (SNP) | VAF 68/561 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FAM170A | c.180C>T p.C60= | Silent (SNP) | VAF 232/670 reads (35%) | catalogued as rs1369318724; called by muse, mutect2
- MYO1D | c.2864+10627A>G | Intron (SNP) | VAF 15/381 reads (4%) | called by muse, mutect2
